Somatic mutation profile of tumor specimen C3L-01607-01 (aliquot CPT0092160009) from CPTAC case C3L-01607, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 83.4 years (30,462 days).
Specimen C3L-01607-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7817f920-e974-48c4-aa5c-da6d46a51aa1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01607-31 (Blood Derived Normal), aliquot CPT0093750002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14da2ca6-d3b1-4d10-985a-556696cef564

The open-access MAF lists 132 somatic variants for this specimen: 91 protein-altering or splice-affecting, 23 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 23, Frame Shift Del 8, Intron 7, 3'UTR 6, Nonsense Mutation 4, Splice Site 3, RNA 2, 5'Flank 2, Splice Region 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB3 | c.880G>A p.V294M | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs747355273; called by muse, mutect2, varscan2
- BBX | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 74/279 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772688060, COSV57881501; called by muse, mutect2, varscan2
- CELSR2 | c.8533C>T p.P2845S | Missense Mutation (SNP) | VAF 31/256 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs1218934903; called by muse, mutect2, varscan2
- CLMN | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs764773895, COSV54190261; called by muse, mutect2
- CYP2A13 | c.773C>A p.T258K | Missense Mutation (SNP) | VAF 47/256 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs138089886, COSV57836209; called by muse, mutect2, varscan2
- DCUN1D3 | c.488G>C p.C163S | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.082); catalogued as rs770510257; called by muse, mutect2, varscan2
- DHRS9 | c.384G>C p.E128D | Missense Mutation (SNP) | VAF 49/299 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as rs1439921018, COSV59139683; called by muse, mutect2, varscan2
- EIF5A | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 58/330 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.308); catalogued as COSV100222692; called by muse, mutect2, varscan2
- ESX1 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV65424475; called by muse, mutect2, varscan2
- EXOC5 | c.887G>T p.R296M | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV61770803; called by muse, mutect2, varscan2
- FAM71B | c.1328G>C p.S443T | Missense Mutation (SNP) | VAF 38/316 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs767349540, COSV57231403; called by muse, mutect2, varscan2
- FOXD4 | c.22C>G p.R8G | Missense Mutation (SNP) | VAF 51/475 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as COSV58700483; called by muse, mutect2, varscan2
- FYB2 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV58587469; called by muse, mutect2
- GRIP2 | c.935C>G p.A312G (on ENST00000619221; = p.A215G on NM_001080423.4) | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV56119861; called by muse, mutect2
- GTF2H1 | c.1418G>A p.R473Q | Missense Mutation (SNP) | VAF 33/268 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as rs551071012, COSV56377387; called by muse, varscan2
- KMT2D | c.5140C>A p.P1714T | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV56494634; called by muse, mutect2, varscan2
- MAPT | c.1135C>T p.H379Y (on ENST00000262410 / NM_001377265.1; = p.H304Y on NM_016835.4) | Missense Mutation (SNP) | VAF 61/447 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1213524576, COSV99291158, COSV99291236; called by muse, mutect2, varscan2
- RASSF10 | c.670C>G p.R224G | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs994986909; called by muse, mutect2
- SLC3A2 | c.1711G>T p.D571Y | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as rs931124662; called by muse, mutect2, varscan2
- SUZ12 | c.1278A>T p.L426F | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as rs773744548; called by muse, mutect2, varscan2
- THSD7A | c.2466G>C p.K822N | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV70265705; called by muse, mutect2, varscan2
- TMEM25 | c.974_976del p.N325del | In Frame Del (DEL) | VAF 41/257 reads (16%) | catalogued as rs1555061837; called by pindel, varscan2
- TOMM6 | c.38C>G p.S13W | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.344); catalogued as COSV59253244; called by muse, mutect2
- AHDC1 | c.3638C>A p.S1213Y | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- AMH | c.373C>A p.P125T | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.23); called by muse, mutect2
- ATP2C1 | c.2129G>A p.S710N | Missense Mutation (SNP) | VAF 41/250 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BPIFB6 | c.267A>C p.Q89H | Missense Mutation (SNP) | VAF 39/242 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- C1GALT1 | c.158A>C p.D53A | Missense Mutation (SNP) | VAF 48/297 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC32 | c.349C>G p.Q117E | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- CD4 | c.1304T>A p.I435N | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CERS1 | c.822_823insT p.V275Cfs*3 | Frame Shift Ins (INS) | VAF 26/222 reads (12%) | called by mutect2, pindel, varscan2
- CFAP43 | c.2495A>C p.E832A | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CHST9 | c.1080T>A p.C360* | Nonsense Mutation (SNP) | VAF 48/299 reads (16%) | called by muse, mutect2, varscan2
- CRP | c.439G>C p.A147P | Missense Mutation (SNP) | VAF 73/449 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CTDSPL2 | c.973del p.Y325Mfs*2 | Frame Shift Del (DEL) | VAF 19/169 reads (11%) | called by mutect2, pindel, varscan2
- CTSA | c.616A>G p.N206D | Missense Mutation (SNP) | VAF 75/480 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- DEFB118 | c.352_364del p.N118Afs*26 | Frame Shift Del (DEL) | VAF 24/149 reads (16%) | called by mutect2, pindel, varscan2
- DLG5 | c.895C>G p.L299V | Missense Mutation (SNP) | VAF 42/259 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- DPYSL3 | c.923G>T p.S308I | Missense Mutation (SNP) | VAF 11/242 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2
- ECT2L | c.193T>A p.W65R | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.115); called by muse, varscan2
- EDC4 | c.1606C>G p.P536A | Missense Mutation (SNP) | VAF 13/346 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2
- EVPL | c.1624G>T p.E542* | Nonsense Mutation (SNP) | VAF 36/238 reads (15%) | called by muse, mutect2, varscan2
- FAM186B | c.466T>A p.C156S | Missense Mutation (SNP) | VAF 69/505 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- FAM227A | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 32/312 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GET1 | c.238A>G p.N80D | Missense Mutation (SNP) | VAF 8/177 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.097); called by muse, mutect2
- GON4L | c.5996T>C p.V1999A | Missense Mutation (SNP) | VAF 44/284 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HIGD1A | c.134del p.L45Yfs*4 | Frame Shift Del (DEL) | VAF 39/229 reads (17%) | called by mutect2, pindel, varscan2
- HTATSF1 | c.2201_2208del p.E734Afs*12 | Frame Shift Del (DEL) | VAF 25/84 reads (30%) | called by mutect2, pindel, varscan2
- HYKK | c.783del p.Y262Mfs*12 | Frame Shift Del (DEL) | VAF 55/399 reads (14%) | called by mutect2, pindel, varscan2
- IFT22 | c.305G>A p.W102* | Nonsense Mutation (SNP) | VAF 13/352 reads (4%) | called by muse, mutect2
- IL9 | c.252A>T p.R84S | Missense Mutation (SNP) | VAF 15/397 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, mutect2
- IRF8 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 51/436 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- KCNG1 | c.1280A>G p.Y427C | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KDM5C | c.3682A>T p.T1228S | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- KDM5C | c.3121-15_3133del p.X1041_splice | Splice Site (DEL) | VAF 17/195 reads (9%) | called by mutect2, pindel
- KNG1 | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 40/237 reads (17%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- KRCC1 | c.440G>C p.S147T | Missense Mutation (SNP) | VAF 34/253 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KRT24 | c.959A>T p.Q320L | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2
- LIN28A | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 30/208 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MGA | c.8713G>C p.E2905Q (on ENST00000219905 / NM_001164273.1; = p.E2696Q on NM_001080541.2) | Missense Mutation (SNP) | VAF 40/264 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- MINK1 | c.2011A>G p.R671G | Missense Mutation (SNP) | VAF 41/267 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- MINK1 | c.2012G>T p.R671M | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MROH9 | c.1440T>A p.D480E | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NACA | c.235-1G>T p.X79_splice | Splice Site (SNP) | VAF 26/130 reads (20%) | called by muse, mutect2, varscan2
- PARD3 | c.1147A>G p.S383G | Missense Mutation (SNP) | VAF 79/391 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- PARD6B | c.518T>C p.I173T | Missense Mutation (SNP) | VAF 51/258 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PBRM1 | c.3604A>C p.T1202P (on ENST00000296302 / NM_001366071.2; = p.T1177P on NM_018313.5) | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA6 | c.122A>G p.H41R | Missense Mutation (SNP) | VAF 51/365 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PCLO | c.9839T>A p.M3280K | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- PSD | c.943A>G p.I315V | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.351); called by muse, mutect2
- RPL10A | c.67C>G p.R23G | Missense Mutation (SNP) | VAF 56/314 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEL1L3 | c.2586-16_2586-5del | Splice Region (DEL) | VAF 30/132 reads (23%) | called by mutect2, pindel
- SH2B1 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- SKP1 | c.370G>C p.A124P | Missense Mutation (SNP) | VAF 64/506 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC25A13 | c.1514C>A p.A505D | Missense Mutation (SNP) | VAF 65/545 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SLC25A13 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 65/555 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SMO | c.1526T>A p.I509N | Missense Mutation (SNP) | VAF 8/244 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2
- SMYD4 | c.502G>T p.D168Y | Missense Mutation (SNP) | VAF 41/324 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- SPTAN1 | c.2967G>T p.K989N | Missense Mutation (SNP) | VAF 57/398 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SPTAN1 | c.2968A>T p.K990* | Nonsense Mutation (SNP) | VAF 56/389 reads (14%) | called by muse, mutect2, varscan2
- STRA6 | c.1721T>A p.V574D | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2
- SV2B | c.1724T>C p.I575T | Missense Mutation (SNP) | VAF 64/465 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- TERT | c.1951-1G>A p.X651_splice | Splice Site (SNP) | VAF 14/409 reads (3%) | called by muse, mutect2
- TEX14 | c.2507del p.P836Lfs*73 (on ENST00000240361 / NM_001201457.2; = p.P830Lfs*73 on NM_031272.5) | Frame Shift Del (DEL) | VAF 20/210 reads (10%) | called by mutect2, pindel
- THSD7B | c.4468G>A p.G1490R (on ENST00000272643; = p.G1488R on NM_001316349.2) | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); called by muse, varscan2
- TOX4 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- VHL | c.387_390del p.V130Tfs*28 | Frame Shift Del (DEL) | VAF 64/371 reads (17%) | called by mutect2, pindel, varscan2
- ZCCHC14 | c.1382T>A p.L461Q (on ENST00000268616; = p.L598Q on NM_015144.3) | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZDHHC2 | c.450T>G p.I150M | Missense Mutation (SNP) | VAF 39/253 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ZFPM1 | c.387del p.R130Gfs*9 | Frame Shift Del (DEL) | VAF 26/232 reads (11%) | called by mutect2, pindel, varscan2
- ZNF687 | c.3065T>C p.V1022A | Missense Mutation (SNP) | VAF 40/262 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ACACA | c.5250C>T p.R1750= | Silent (SNP) | VAF 79/484 reads (16%) | called by muse, mutect2, varscan2
- CACNA2D3 | c.501C>T p.I167= | Silent (SNP) | VAF 8/158 reads (5%) | called by muse, mutect2
- CD4 | c.1305C>T p.I435= | Silent (SNP) | VAF 26/258 reads (10%) | catalogued as COSV50589947; called by muse, mutect2
- CPT1A | c.189T>A p.L63= | Silent (SNP) | VAF 61/417 reads (15%) | called by muse, mutect2, varscan2
- DCUN1D4 | c.513T>C p.D171= | Silent (SNP) | VAF 18/144 reads (13%) | called by muse, mutect2
- GPLD1 | c.1062C>T p.F354= | Silent (SNP) | VAF 29/191 reads (15%) | called by muse, mutect2, varscan2
- HEXA | c.882C>T p.L294= | Silent (SNP) | VAF 16/452 reads (4%) | called by muse, mutect2
- KIF19 | c.1995C>T p.P665= | Silent (SNP) | VAF 42/198 reads (21%) | catalogued as rs1016773272, COSV63430705; called by muse, mutect2, varscan2
- KMT2B | c.4224C>A p.A1408= | Silent (SNP) | VAF 26/137 reads (19%) | called by muse, mutect2, varscan2
- MAPT | c.1791T>C p.T597= (on ENST00000262410 / NM_001377265.1; = p.T205= on NM_005910.5) | Silent (SNP) | VAF 45/335 reads (13%) | called by muse, mutect2, varscan2
- MB | c.345T>G p.V115= | Silent (SNP) | VAF 15/99 reads (15%) | called by muse, mutect2, varscan2
- NALCN | c.114T>G p.V38= | Silent (SNP) | VAF 12/87 reads (14%) | called by muse, mutect2, varscan2
- PDLIM7 | c.1251G>C p.L417= | Silent (SNP) | VAF 14/178 reads (8%) | called by muse, mutect2
- PEG10 | c.768G>A p.A256= (on ENST00000482108 / NM_001040152.2; = p.A290= on NM_015068.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/186 reads (8%) | called by muse, mutect2
- RHOXF2 | c.396C>T p.N132= | Silent (SNP) | VAF 70/402 reads (17%) | catalogued as rs782065383; called by muse, mutect2, varscan2
- SH3RF3 | c.2259C>T p.D753= | Silent (SNP) | VAF 28/139 reads (20%) | catalogued as rs1322906700; called by muse, mutect2, varscan2
- SLC16A2 | c.996C>T p.A332= | Silent (SNP) | VAF 72/223 reads (32%) | catalogued as rs1232946549; called by muse, mutect2, varscan2
- SLFNL1 | c.597T>C p.S199= | Silent (SNP) | VAF 18/144 reads (13%) | called by muse, mutect2, varscan2
- SP1 | c.57A>G p.K19= (on ENST00000327443 / NM_138473.3; = p.K12= on NM_003109.1) | Silent (SNP) | VAF 19/127 reads (15%) | called by muse, mutect2, varscan2
- TBX6 | c.1215A>G p.V405= | Silent (SNP) | VAF 40/231 reads (17%) | called by muse, mutect2, varscan2
- TOGARAM2 | c.1386G>A p.T462= | Silent (SNP) | VAF 39/242 reads (16%) | catalogued as rs527747733, COSV65423208; called by muse, mutect2, varscan2
- UQCR10 | c.168C>T p.I56= | Silent (SNP) | VAF 52/264 reads (20%) | called by muse, mutect2, varscan2
- ZMYM2 | c.1794A>G p.T598= | Silent (SNP) | VAF 31/213 reads (15%) | called by muse, mutect2, varscan2
- AC107023.1 | chr12:40444228 C>T | 5'Flank (SNP) | VAF 17/397 reads (4%) | catalogued as rs1461313887; called by muse, mutect2
- BIRC8 | n.1459T>A | RNA (SNP) | VAF 44/269 reads (16%) | called by muse, mutect2, varscan2
- CD276 | c.*36G>A | 3'UTR (SNP) | VAF 14/82 reads (17%) | called by muse, mutect2, varscan2
- ECM2 | chr9:92536054 del TGC | 5'UTR (DEL) | VAF 37/251 reads (15%) | called by mutect2, pindel, varscan2
- EIF4E | c.*42C>A | 3'UTR (SNP) | VAF 26/135 reads (19%) | called by muse, mutect2, varscan2
- GP2 | chr16:20327559 T>A | 5'Flank (SNP) | VAF 67/349 reads (19%) | called by muse, mutect2, varscan2
- HNRNPH1 | c.*21T>C | Intron (SNP) | VAF 8/72 reads (11%) | catalogued as COSV61486881; called by muse, mutect2
- IFT52 | c.*19C>G | 3'UTR (SNP) | VAF 29/221 reads (13%) | called by muse, mutect2, varscan2
- KLF6 | c.*1324T>G | 3'UTR (SNP) | VAF 8/248 reads (3%) | called by muse, mutect2
- MARK2 | c.55-6234A>G | Intron (SNP) | VAF 37/265 reads (14%) | called by muse, mutect2, varscan2
- MEIS2 | c.1147+408G>A | Intron (SNP) | VAF 51/252 reads (20%) | called by muse, mutect2, varscan2
- NCKAP1 | c.3181-34A>C | Intron (SNP) | VAF 28/177 reads (16%) | called by muse, mutect2, varscan2
- PDE3B | c.1029+100_1029+102del | Intron (DEL) | VAF 11/87 reads (13%) | called by mutect2, pindel, varscan2
- REXO1L1P | n.766C>A | RNA (SNP) | VAF 35/594 reads (6%) | called by muse, mutect2
- SEPTIN1 | c.*221C>A | 3'UTR (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
- TMA16 | c.*528C>G | 3'UTR (SNP) | VAF 10/144 reads (7%) | catalogued as rs1019892970; called by muse, mutect2
- TPM1 | c.772+68C>G | Intron (SNP) | VAF 55/359 reads (15%) | called by muse, mutect2, varscan2
- VASP | c.873+16T>A | Intron (SNP) | VAF 37/254 reads (15%) | called by muse, mutect2, varscan2
